Surgical pathology report (de-identified scan), TCGA case TCGA-DX-A1L3, project TCGA-SARC (Sarcoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DX-A1L3-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

Patient: [REDACTED] Accession #: [REDACTED]
MRN: [REDACTED] Service: Gastric & Mixed Tumo
Account #: [REDACTED] Date of Procedure:
DOB: [REDACTED] Date of Receipt:
Physician: [REDACTED]
CC: [REDACTED]

Specimens Submitted:

1: SP: Radical resection right peritoneal liposarcom

DIAGNOSIS:

1. SOFT TISSUE, RETROPERITONEUM, RIGHT; RESECTION:
- DEDIFFERENTIATED LIPOSARCOMA. SEE NOTE
- TUMOR SIZE: 20.0 x 15.5 x 14.5 CM.
- NECROSIS COMPRISES ABOUT 20-25% OF THE TUMOR VOLUME (GROSS ESTIMATE).
- A SMALL COMPONENT OF WELL DIFFERENTIATED LIPOSARCOMA, LIPOMA-LIKE IS PRESENT.
- TUMOR IS FOCALLY PRESENT AT INKED MARGIN.

NOTE: THE DEDIFFERENTIATED COMPONENT HAS A LOW GRADE FIBROSARCOMA-LIKE APPEARANCE SIMILAR TO PREVIOUS MATERIAL

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

1.) The specimen is received fresh labeled "radical resection of right peritoneal liposarcoma" and consists of a rubbery nodular mass measuring 20.0 x 15.5 x 14.5 cm. The tumor is surrounded by soft fibrous membrane and portions of fibroadipose tissue are attached. Sectioning reveals tan white whorled cut surface with central area of necrosis involving about 20 to 25% of the tumor volume. The surgical margin is inked black. TPS is taken. Gross photograph is taken. Representative sections are submitted.

Summary of sections:

** Continued on next page **

100-0-3
De differentiated liposarcoma 8858/3
Site: retroperitoneum C48.0
2/2/11
m

[page 2 of 2]
SURGICAL PATHOLOGY REPORT

Patient:

MRN:

Account #:

Accession #:

Physician:

Service: Gastric & Mixed Tumo

Page 2 of 2

TM - tumor to margin

T tumor

TN - tumor necrosis

Summary of Sections:

Part 1: SP: Radical resection right peritoneal liposarcom

Block	Sect.	Site	PCs
1		{not entered}	
9		T	9
5		TM	5
5		TN	5

** End of Report **

Diagnostic Discrepancy		/

Source: NCI Genomic Data Commons file 74e402b5-d77a-4eaa-b577-513ed7cf1b06 (TCGA-DX-A1L3.2E82135A-E73A-4A74-8A01-B610AE65FC37.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).